Somatic mutation profile of tumor specimen C3N-00179-03 (aliquot CPT0019940009) from CPTAC case C3N-00179, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.5 years (25,370 days).
Specimen C3N-00179-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13b8f334-fd33-4a9d-9238-20face4ad230.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00179-31 (Blood Derived Normal), aliquot CPT0020950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83a3ad31-79ed-4249-8ebd-2b65bf9f8637

The open-access MAF lists 42 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Intron 7, Silent 6, Nonsense Mutation 2, Splice Region 1, 5'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.6977G>T p.R2326L | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852360, CD101348, CM012947, CM860009, CM890047, COSV100371798; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP32 | c.2380G>T p.D794Y (on ENST00000310343 / NM_001378025.1; = p.D445Y on NM_014715.4) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59852624; called by muse, mutect2, varscan2
- BTNL3 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61564956; called by muse, mutect2
- DNAJC13 | c.4480A>T p.I1494F | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99608162; called by muse, mutect2, varscan2
- OR2B3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs761688447, COSV65851237; called by muse, mutect2, varscan2
- PDILT | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 282/569 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1395536984; called by muse, mutect2, varscan2
- SLC1A4 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768616901, COSV52235413; called by muse, mutect2
- TNRC6B | c.3790C>T p.Q1264* (on ENST00000454349 / NM_001162501.2; = p.Q1154* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 9/183 reads (5%) | catalogued as COSV57306177; called by muse, mutect2
- TTPA | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 27/290 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV52647734; called by muse, mutect2
- VWF | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 36/588 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.208); catalogued as COSV54635354; called by muse, mutect2
- ZNF451 | c.2897A>G p.D966G (on ENST00000370706 / NM_001031623.3; = p.D918G on NM_015555.2) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758659256; called by muse, mutect2
- ACSBG2 | c.1235T>C p.L412S | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1A2 | c.750C>T p.G250= | Splice Region (SNP) | VAF 49/398 reads (12%) | called by muse, mutect2, varscan2
- CHGB | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- CPNE2 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.023); called by muse, mutect2
- DOCK2 | c.137G>T p.R46M | Missense Mutation (SNP) | VAF 11/159 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2
- GRAMD1B | c.2087G>T p.W696L | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ILKAP | c.328T>C p.Y110H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.142); called by muse, mutect2
- KMO | c.1128C>A p.F376L | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- LMAN1L | c.1465A>G p.K489E | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, varscan2
- LRRIQ1 | c.1913_1914insT p.K638Nfs*6 | Frame Shift Ins (INS) | VAF 3/37 reads (8%) | called by mutect2, pindel
- LTB4R | c.433T>G p.S145A | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OS9 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 43/411 reads (10%) | called by muse, mutect2, varscan2
- PDILT | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 353/720 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SCNN1A | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- ZNF808 | c.1244C>A p.A415E | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2
- ACTR8 | c.432A>T p.R144= | Silent (SNP) | VAF 9/124 reads (7%) | catalogued as COSV99213707; called by muse, mutect2
- CEACAM1 | c.483T>C p.D161= | Silent (SNP) | VAF 24/413 reads (6%) | called by muse, mutect2
- DOK4 | c.198G>A p.K66= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as COSV99538257; called by muse, mutect2, varscan2
- MTBP | c.216T>A p.G72= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- RPUSD2 | c.1566C>T p.R522= | Silent (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2, varscan2
- SVIL | c.561C>T p.L187= | Silent (SNP) | VAF 25/282 reads (9%) | catalogued as COSV63447209; called by muse, mutect2
- ADAMTS13 | c.825-93A>G | Intron (SNP) | VAF 21/171 reads (12%) | called by muse, mutect2, varscan2
- CCDC162P | n.1813-2572C>T | Intron (SNP) | VAF 9/117 reads (8%) | catalogued as rs907254607; called by muse, mutect2
- ITGB3BP | c.6-1602C>T | Intron (SNP) | VAF 5/42 reads (12%) | catalogued as rs960046344, COSV52132683; called by muse, varscan2
- KIF7 | c.2593-24C>T | Intron (SNP) | VAF 137/468 reads (29%) | catalogued as rs760175118; called by muse, mutect2, varscan2
- LINC02448 | n.478G>C | RNA (SNP) | VAF 39/304 reads (13%) | called by muse, varscan2
- LSS | c.*39-912G>T | Intron (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- MLIP | c.612+11989G>A | Intron (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- TMEM167A | c.-47C>T | 5'UTR (SNP) | VAF 49/143 reads (34%) | called by muse, mutect2, varscan2
- ZNF528 | c.272-112C>T | Intron (SNP) | VAF 13/182 reads (7%) | called by muse, mutect2
